Somatic mutation profile of tumor specimen TCGA-AP-A05J-01A (aliquot TCGA-AP-A05J-01A-11W-A027-09) from TCGA case TCGA-AP-A05J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.0 years (24,119 days).
Specimen TCGA-AP-A05J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38eac24a-b048-486e-ad02-8d850546f50d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A05J-10A (Blood Derived Normal), aliquot TCGA-AP-A05J-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb8fd47d-a021-4d43-a540-d80a0a7d9751

The open-access MAF lists 50 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 39, Silent 9, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 78/184 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 49/57 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.98T>C p.L33S | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV65534418; called by muse, mutect2, varscan2
- ALDH18A1 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100973309, COSV64662153; called by muse, mutect2, varscan2
- ARHGAP35 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.837); catalogued as COSV68329437; called by muse, mutect2, varscan2
- ARMS2 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.867); catalogued as COSV73306981; called by muse, mutect2
- CNGB3 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60685532, COSV60688836; called by muse, mutect2, varscan2
- CNOT8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV53585073, COSV99597211; called by muse, mutect2, varscan2
- DCHS1 | c.7768G>A p.V2590I | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54996256; called by muse, mutect2, varscan2
- DOCK10 | c.1720A>G p.R574G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs1252733944, COSV51351766; called by muse, mutect2, varscan2
- E2F4 | c.944G>C p.S315T | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV62605994; called by muse, mutect2, varscan2
- ELP6 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.121); catalogued as rs370492398; called by muse, mutect2, varscan2
- ENTPD4 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 107/124 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62268368; called by muse, mutect2, varscan2
- GNS | c.1130C>T p.T377I | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50694006; called by muse, mutect2, varscan2
- GPALPP1 | c.975A>T p.R325S | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV62705433; called by muse, mutect2, varscan2
- KIR3DL3 | c.1198A>G p.R400G | Missense Mutation (SNP) | VAF 327/783 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV52545871; called by muse, mutect2, varscan2
- LAP3 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV56898580, COSV99884126; called by muse, mutect2, varscan2
- MB21D2 | c.919A>G p.M307V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV66661912; called by muse, mutect2, varscan2
- MCTP1 | c.2816T>C p.I939T | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768842714, COSV56505760; called by muse, mutect2, varscan2
- MRPL47 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 131/240 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV52022469; called by muse, mutect2, varscan2
- MUC3A | c.7168C>A p.P2390T | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT deleterious, low confidence (0); catalogued as COSV60211406; called by muse, mutect2, varscan2
- NPAS4 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs770386876, COSV60649051; called by muse, mutect2, varscan2
- PCDHA4 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1379248044, COSV63539339; called by muse, mutect2, varscan2
- POU3F2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV60408535; called by muse, mutect2, varscan2
- PPP1R17 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.255); catalogued as COSV59610709; called by muse, mutect2, varscan2
- PRDM1 | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV64844550; called by muse, mutect2, varscan2
- RPL10L | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV53558793; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.26T>C p.I9T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.027); catalogued as rs776004367, COSV58241777; called by muse, mutect2, varscan2
- RYR2 | c.10979G>T p.R3660I | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV100772124, COSV63658499, COSV63665973; called by muse, mutect2, varscan2
- SACS | c.8038G>T p.D2680Y | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66535318; called by muse, mutect2, varscan2
- SEC31A | c.2987A>G p.N996S (on ENST00000355196 / NM_001318120.1; = p.N957S on NM_016211.4) | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV52342026; called by muse, mutect2, varscan2
- SLC15A4 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV57160519; called by muse, mutect2, varscan2
- SLC2A2 | c.1120A>C p.S374R | Missense Mutation (SNP) | VAF 132/327 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV58584805; called by muse, mutect2, varscan2
- SLC37A1 | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV61401480; called by muse, mutect2, varscan2
- SOX17 | c.1133C>G p.P378R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV52024427, COSV52028402, COSV99810860; called by muse, mutect2
- SV2A | c.1584T>G p.D528E | Missense Mutation (SNP) | VAF 128/269 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1559787372, COSV64964335; called by muse, mutect2, varscan2
- TENM1 | c.1813G>A p.G605S | Missense Mutation (SNP) | VAF 183/392 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372307543, COSV64426035; called by muse, mutect2, varscan2
- TOX3 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1249328563, COSV54863323; called by muse, mutect2, varscan2
- UCHL1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV52651086, COSV52652296; called by muse, mutect2, varscan2
- UEVLD | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs757673514, COSV57873389; called by muse, mutect2, varscan2
- ARHGAP35 | c.597_600del p.T200Sfs*18 | Frame Shift Del (DEL) | VAF 41/108 reads (38%) | called by mutect2, pindel, varscan2
- BCOR | c.2124C>T p.T708= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs749386912, COSV60701342; ClinVar: benign; called by muse, mutect2, varscan2
- BTNL2 | c.1254C>T p.H418= | Silent (SNP) | VAF 84/198 reads (42%) | catalogued as rs144584698, COSV66630254; called by muse, mutect2, varscan2
- FRMPD3 | c.1359C>T p.G453= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as rs1207294499, COSV52187119; called by muse, mutect2, varscan2
- ITGAL | c.1947T>C p.N649= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV63320383; called by muse, mutect2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 107/256 reads (42%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- OR6N1 | c.633C>T p.F211= | Silent (SNP) | VAF 145/324 reads (45%) | catalogued as COSV58647506; called by muse, mutect2, varscan2
- PRRC2B | c.3996C>A p.P1332= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as COSV61934291; called by muse, mutect2, varscan2
- RYR2 | c.10833G>T p.L3611= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV63665966; called by muse, mutect2, varscan2
- SIX6 | c.360G>C p.P120= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV59801655, COSV59802139; called by muse, mutect2, varscan2
